CCG case CUPP-B6BQ — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/de308c15-3f96-4b61-b786-4f95c8a28486

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Year of birth: 1931; Vital status: Dead; Days to death: 96 days; Year of death: 2010; Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 78.4 years (28,651 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: TX; AJCC clinical N: NX; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Liver / Lung, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R2; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (2 entries)
- Day 0 (initial diagnosis): ECOG performance status: 3.
- Days to follow up: 96 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Other.
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 160 cm; BMI: 34.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Gastric Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B6BQ-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B6BQ-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 75; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
